Surgical pathology report (de-identified scan), TCGA case TCGA-QK-A8ZB, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Emory University - Winship Cancer Inst., specimen TCGA-QK-A8ZB-01A (Primary Tumor).

[page 1 of 5]
Document Type: Anat Path Reports
Document Date:
Document Status: Auth (Verified)
Document Title: Histology
Performed By:
Verified By:
Encounter info:

ICD O-3
Carcinoma, squamous cell NOS
8670/3
Site Larynx NOS C32.9
path Glottis C32.0
9/11/14

* Final Report *

Patient Name: [REDACTED]
MRN: [REDACTED]
Location:
Client:
Submitting Phys:
Copy To Phys:

Acc #: [REDACTED]
DOB: [REDACTED]
Gender: M
Collected:
Received:
Reported:
Head and Neck

Final Surgical Pathology Report

Final Pathologic Diagnosis

- A. LARYNX, TOTAL LARYNGECTOMY:
- INVASIVE SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED (2.5 X 2.2 X 1.9 CM).
- TUMOR INVOLVES THE LEFT TRUE VOCAL CORD, VENTRICLE, ANTERIOR COMMISSURE, AND INVADERS THROUGH THE THYROID CARTILAGE.
- SUBCUTANEOUS TISSUE WITH ABSCESS AND KERATINACEOUS DEBRIS.
- SURGICAL MARGINS NEGATIVE.
- SEE SYNOPTIC REPORT.
- B. LYMPH NODES, LEVEL 1A, EXCISION:
- THREE LYMPH NODES NEGATIVE FOR CARCINOMA (0/3).
- C. LYMPH NODES, LEFT NECK LEVEL 2B, EXCISION:
- EIGHT LYMPH NODES NEGATIVE FOR CARCINOMA (0/8).
- D. LYMPH NODES, RIGHT NECK LEVEL 2A, EXCISION:
- TWELVE LYMPH NODES NEGATIVE FOR CARCINOMA (0/12).
- E. LYMPH NODES, RIGHT NECK LEVEL 3, EXCISION:
- ELEVEN LYMPH NODES NEGATIVE FOR CARCINOMA (0/11).
- F. LYMPH NODES, RIGHT NECK LEVEL 4, EXCISION:
- EIGHT LYMPH NODES NEGATIVE FOR CARCINOMA (0/8).
- G. LYMPH NODES, LEFT NECK LEVEL 2, EXCISION:
- TWELVE LYMPH NODES NEGATIVE FOR CARCINOMA (0/12).
- H. LYMPH NODES, LEFT NECK LEVEL 3, EXCISION:
- TWENTY LYMPH NODES NEGATIVE FOR CARCINOMA (0/20).
- I. LYMPH NODES, LEFT NECK LEVEL 4, EXCISION:
- SEVEN LYMPH NODES NEGATIVE FOR CARCINOMA (0/7).

[page 2 of 5]
Electronically Signed by

Synoptic Worksheet

A. Total laryngectomy (study case):

Clinical History:	No Neoadjuvant therapy
Specimen:	Larynx, glottis
Received:	Fresh
Procedure:	Total laryngectomy
	Neck (lymph node) dissection: Level 1A, Left neck (2B, 2, 3, 4), Right neck (2A, 3, 4)
Specimen Integrity:	Intact
Laryngectomy:	Unopened
Specimen Size:	Greatest dimension: 9.3 cm
	Additional dimension: 5.2 cm
	Additional dimension: 4.3 cm
Tumor Laterality:	Left
Tumor Site:	Larynx, glottis, true vocal cord
	Larynx, glottis, anterior commissure
Transglottic:	No
Additional Sites Involved by Tumor:	
	Ventricle
Tumor Focality:	Single focus
Tumor Description:	Endophytic
	Ulcerated
Histologic Type:	Squamous cell carcinoma, conventional
Histologic Grade:	G2: Moderately differentiated
Tumor Size:	Greatest dimension: 2.5 cm
	Additional dimension: 1.9 cm
	Additional dimension: 2.2 cm
Margins:	Margins uninvolved by invasive carcinoma
	Margins uninvolved by carcinoma in situ (includes moderate and severe dysplasia)
Treatment Effect:	Not identified: _____
Lymph-Vascular Invasion:	Not identified: _____

Perineural Invasion:	Not identified: _____

Lymph Nodes, Extranodal Extension:	Not identified: _____

Primary Tumor (pT):	Glottis pT4a: Moderately advanced local disease. Tumor invades through the outer cortex of the thyroid cartilage and/or invades tissues beyond the larynx (eg, trachea, soft tissues of neck including deep extrinsic muscle of the tongue, strap muscles, thyroid, or esophagus)
Regional Lymph Nodes (pN):	pN0: No regional lymph node metastasis Number of regional lymph nodes examined: 81 Number of regional lymph nodes involved: none identified
Distant Metastasis (pM):	Not applicable: not applicable

[page 3 of 5]
Mucosal Melanoma Distant Metastasis (pM):

Not applicable:

Additional Pathologic Findings:

Inflammation (type): abscess involving subcutaneous tissue with keratin debris

Clinical History

Laryngeal cancer. Total laryngectomy, neck dissection, pectoralis flap, direct laryngoscopy.

Specimen(s) Received

A: Total laryngectomy (study case)
B: Level 1A
C: Left neck 2B
D: Right neck level 2A
E: Right neck level 3
F: Right neck level 4
G: Left neck level 2
H: Left neck level 3
I: Left neck level 4

Gross Description

Specimen A is received fresh in a container labeled with the patient's name, medical record number and identified as "total laryngectomy." The specimen consists of a total laryngectomy specimen measuring 9.3 x 5.2 x 4.3 cm in total dimension from the tip of the epiglottis to the inferior tracheal edge with attached hyoid bone measuring 9.5 x 0.5 x 0.7 cm and the left thyroid lobe measuring 4.1 x 3.3 x 2.2 cm. The larynx is opened posteriorly on the midline at the time of frozen section analysis. There are three tracheal rings attached.

There is a tan-white appearing mass measuring 2.5 x 1.9 cm in surface area and 2.2 cm in thickness involving the glottic larynx. The mass is grossly located on the bilateral false cord, vestibule true cord and crosses the midline. The mass does not appear to involve pyriform sinus. Grossly, the mass extends 2.4 cm from the tip of the epiglottic mucosal edge, 2.3 cm from the base of the tongue mucosal edge, 2.4 cm from the lateral right mucosal edge, 1.1 cm from the lateral left mucosal edge and 3.1 cm from the distal tracheal edge. None of the tracheal rings grossly appear involved the mass. On the anterior aspect of the specimen is an ellipse of abnormal skin measuring 4.5 x 4.3 x 1.0 cm. The inferior aspect of the skin ellipse measures 2.3 cm from the distal tracheal edge. A tan-white, irregular ulceration is identified measuring 2.2 x 1.7 cm and is present 2.5 cm from the inferior skin edge, 1.6 cm from the left skin edge, 1.1 cm from the right skin edge and 0.9 cm from the superior skin edge. The skin defect grossly does not appear to communicate with the mass lesion. There is a left lobe of the thyroid gland present. The cut surface is homogenous and beefy red. A colloid nodule measuring 1.3 x 1.1 x 0.5 cm is noted. On sectioning, the lesion grossly invades the anterior commissure as well as the pre-epiglottic space as well as possible full thickness invasion of the thyroid cartilage. Sections are taken as listed in the cassette summary after decalcification. Representative section of tumor is submitted for Tumor Bank at the time of frozen section analysis. The specimen is inked as listed in the inking code. Dictated by

Ink Code:

Left – blue
Right – black

CASSETTE SUMMARY:

A1FS – tracheal margin
A2FS – posterior margin
A3FS – right pharyngeal margin
A4FS – left pharyngeal margin
A5FS – tongue base margin
A6 – skin margin, superior shave
A7 – right skin margin, shave
A8FS – inferior skin margin, shave

[page 4 of 5]
A9FS – left skin margin, shave
A10 – right epiglottis, decal
A11,A12 – right false cord, ventricle, true cord and tumor submitted superior to inferiorly, decal
A13 – right aryepiglottic fold, decal
A14 – right anterior soft tissue anterior to the cord
A15-A16 – midline epiglottis (A16 submitted in decal)
A17-A18 – superior anterior commissure and anterior soft tissues and skin submitted deep to superficial (A17 submitted in decal)
A19-A20 – inferior, anterior commissure and anterior soft tissues and skin submitted from deep to superficial
A21 – left aryepiglottic fold
A22 – left epiglottis, decal
A23 – left false cord, decal
A24 – left soft tissues anterior to cord
A25 – left thyroid lobe with colloid nodule, representative sections

Specimens B through I are received in formalin, in containers labeled with the patient's name and medical record number.

Specimen B is identified as "level 1A." The specimen consists of a firm portion of fibrofatty tissue measuring 2.5 x 1.4 x 0.3 cm. The specimen is submitted entirely in cassettes "B1" and "B2." Dictated by

CASSETTE SUMMARY:

B1,2 – level 1A

Specimen C is identified as "left neck level 1B." The specimen consists of a firm portion of fibrofatty tissue measuring 3.0 x 1.4 x 1.3 cm. The specimen is submitted entirely in cassettes "C1" through "C3." Dictated by

CASSETTE SUMMARY:

C1-3 – left neck level 1B, submitted entirely

Specimen D is identified as "right neck level 2A." The specimen consists of a portion of fibrofatty tissue measuring 4.0 x 2.1 x 0.7 cm. Multiple possible lymph nodes are identified. Sections are submitted as listed in the cassette summary. Dictated by

CASSETTE SUMMARY:

D1-3 – multiple possible lymph nodes

Specimen E is identified as "right neck level 3." The specimen consists of two pieces of fibrofatty tissue measuring 4.3 x 3.6 x 1.1 cm in aggregate. The specimen consists of multiple possible lymph nodes. Sections are submitted as listed in the cassette summary. Dictated by

CASSETTE SUMMARY:

E1-3 – multiple possible lymph nodes
E4 – one lymph node, bisected
E5 – one lymph node, bisected

Specimen F is identified as "right neck level 4." The specimen consists of a portion of fibrofatty tissue measuring 3.0 x 2.2 x 0.6 cm. Multiple possible lymph nodes are identified. Sections are submitted as listed in the cassette summary. Dictated by

CASSETTE SUMMARY:

[page 5 of 5]
F1,2 – multiple possible lymph nodes
F3 – one lymph node, bisected
F4 – one lymph node, bisected

Specimen G is identified as "left neck level 2." The specimen consists of multiple pieces of fibrofatty tissue measuring 5.0 x 4.7 x 0.5 cm. Multiple possible lymph nodes are identified. Sections are submitted as listed in the cassette summary. Dictated by

CASSETTE SUMMARY:

G1-3 – multiple possible lymph nodes
G4 – one lymph node, bisected

Specimen H is identified as "left neck level 3." The specimen consists of a portion of fibrofatty tissue measuring 4.1 x 3.0 x 1.0 cm. Multiple possible lymph nodes are identified within the tissue. Sections are submitted as listed in the cassette summary. Dictated by

CASSETTE SUMMARY:

H1-4 – multiple possible lymph nodes
H5 – one lymph node, bisected
H6 – one lymph node, bisected
H7 – one lymph node, bisected

Specimen I is identified as "left neck level 4." The specimen consists of a portion of fibrofatty tissue measuring 3.5 x 2.7 x 1.6 cm. Multiple possible lymph nodes are identified. Sections are submitted as listed in the cassette summary. Dictated by

CASSETTE SUMMARY:

I1,2 – multiple possible lymph nodes
I3,4 – one lymph node

Intraoperative Consult Diagnosis

A1FS-A5FS: LARYNGECTOMY (FROZEN SECTION): MARGINS NEGATIVE, MUCOSAL AND SKIN.
Frozen section results were communicated to the surgical team and were repeated back by

and the specimen is received at

Pathologist:

Source: NCI Genomic Data Commons file ad2335da-0574-45ff-80f3-0e70e88ee16e (TCGA-QK-A8ZB.778AC64D-1AC5-4F43-AF14-DB670D34E3EB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).